Somatic mutation profile of tumor specimen TCGA-D3-A1Q6-06A (aliquot TCGA-D3-A1Q6-06A-11D-A196-08) from TCGA case TCGA-D3-A1Q6, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 55.5 years (20,280 days).
Specimen TCGA-D3-A1Q6-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aee17950-2316-4d25-bee1-694da9063a60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A1Q6-10A (Blood Derived Normal), aliquot TCGA-D3-A1Q6-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffb4884b-6938-442b-9544-b3a6fb27414d

The open-access MAF lists 973 somatic variants for this specimen: 607 protein-altering or splice-affecting, 349 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 550, Silent 349, Nonsense Mutation 39, Splice Site 11, Intron 8, Splice Region 5, 3'UTR 3, RNA 3, 5'Flank 2, Frame Shift Del 1, 3'Flank 1, Translation Start Site 1.

Variants (750 of 973; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GABRG2 | c.1005G>A p.W335* (on ENST00000361925 / NM_001375343.1; = p.W295* on NM_000816.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 43/82 reads (52%) | catalogued as rs1554100509, COSV62715160; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 152/465 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.389); catalogued as rs374090960, CM150594; ClinVar: likely pathogenic; called by mutect2, varscan2
- MAP2K1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1057519732, COSV61068297; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as COSV64674290; called by muse, mutect2, varscan2
- ABCC3 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1336670434, COSV53323338; called by muse, mutect2, varscan2
- ABCC6 | c.2587G>A p.G863R | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV52744653; called by muse, mutect2, varscan2
- ABCC8 | c.4354G>T p.E1452* | Nonsense Mutation (SNP) | VAF 57/147 reads (39%) | catalogued as COSV56851834; called by muse, mutect2, varscan2
- ABCC9 | c.2789C>G p.T930S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV53974728; called by muse, mutect2, varscan2
- ABCD2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58051835; called by muse, mutect2, varscan2
- ABTB2 | c.2558G>A p.G853E | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54389877; called by muse, mutect2, varscan2
- AC013489.1 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1392824115, COSV51551758; called by muse, mutect2, varscan2
- AC093525.2 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | PolyPhen benign (0.003); catalogued as rs1255059601, COSV53551064; called by muse, mutect2, varscan2
- AC104389.6 | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as rs35849660, COSV100400634, COSV57963795; ClinVar: other; called by muse, mutect2, varscan2
- AC136428.1 | c.20G>A p.W7* | Nonsense Mutation (SNP) | VAF 20/118 reads (17%) | catalogued as COSV101434969; called by muse, mutect2, varscan2
- ACP3 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV60486818; called by muse, mutect2, varscan2
- ADAM18 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs779557988, COSV55844959; called by muse, mutect2
- ADAM2 | c.1114C>T p.H372Y | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV55863437; called by muse, mutect2, varscan2
- ADAM21 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV50796514; called by muse, mutect2, varscan2
- ADAM32 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.786); catalogued as rs957652162, COSV65950171; called by muse, mutect2
- ADAMTS18 | c.2179C>T p.H727Y | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV51399503; called by muse, mutect2, varscan2
- ADCY6 | c.2417C>T p.T806I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs1226659148, COSV57168411; called by muse, mutect2, varscan2
- ADGRB3 | c.3532C>T p.P1178S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV53238942, COSV53247980; called by muse, mutect2, varscan2
- ADGRG3 | c.1540+1G>A p.X514_splice | Splice Site (SNP) | VAF 34/115 reads (30%) | catalogued as COSV59651331; called by muse, mutect2, varscan2
- ADGRL2 | c.3955C>T p.H1319Y (on ENST00000370717 / NM_001366005.1; = p.H1263Y on NM_012302.4) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.309); catalogued as COSV54656482; called by muse, mutect2, varscan2
- ADGRV1 | c.791G>A p.R264K | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV67979450, COSV67987240; called by muse, mutect2, varscan2
- ADH1B | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV59296460; called by muse, mutect2
- AHNAK2 | c.10244G>A p.G3415D | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as COSV100317310; called by muse, mutect2, varscan2
- AHNAK2 | c.10243G>A p.G3415S | Missense Mutation (SNP) | VAF 47/297 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as rs745827678, COSV100317312; called by muse, mutect2, varscan2
- ALDOB | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66398034; called by muse, mutect2, varscan2
- ALOX12 | c.431G>A p.W144* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV52350413; called by muse, mutect2, varscan2
- ANGEL1 | c.1906C>T p.L636F | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs747200123, COSV51873786; called by muse, mutect2, varscan2
- ANGPTL6 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV53462636; called by muse, varscan2
- ANK2 | c.5600C>T p.S1867L | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV52166209; called by muse, mutect2, varscan2
- ANKFN1 | c.731A>C p.K244T | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as COSV59449607; called by muse, mutect2, varscan2
- ANO3 | c.2005A>T p.K669* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | catalogued as COSV99882448; called by muse, mutect2
- ANXA2R | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV59214931; called by muse, mutect2, varscan2
- AP1G2 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58113223; called by muse, mutect2, varscan2
- APOF | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV58475954; called by muse, mutect2, varscan2
- ARHGAP24 | c.374G>A p.W125* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV101232733, COSV67829278; called by muse, mutect2, varscan2
- ARHGAP25 | c.1289C>T p.P430L (on ENST00000409202 / NM_001007231.3; = p.P422L on NM_014882.3) | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV54903464; called by muse, mutect2, varscan2
- ARID1B | c.4162C>T p.Q1388* | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | catalogued as rs1554235553, COSV51665299; called by muse, mutect2, varscan2
- ASAP3 | c.2546+2T>C p.X849_splice | Splice Site (SNP) | VAF 11/65 reads (17%) | catalogued as COSV60875402; called by muse, mutect2, varscan2
- ASB15 | c.810T>G p.N270K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51926681; called by muse, mutect2, varscan2
- ASCC3 | c.6409C>T p.R2137* | Nonsense Mutation (SNP) | VAF 78/164 reads (48%) | catalogued as rs760927168, COSV64973923, COSV64977816; called by muse, mutect2, varscan2
- ASTN2 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV57785409; called by muse, mutect2, varscan2
- ATP13A5 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60866119; called by muse, mutect2, varscan2
- ATP2B2 | c.1828C>T p.R610C (on ENST00000352432; = p.R576C on NM_001683.5) | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757018981, COSV100659980, COSV59498430; called by muse, mutect2, varscan2
- ATP2B2 | c.781+2T>G p.X261_splice | Splice Site (SNP) | VAF 28/68 reads (41%) | catalogued as COSV59498438; called by muse, mutect2, varscan2
- B3GAT2 | c.851A>T p.E284V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV57640717; called by muse, mutect2, varscan2
- BACH2 | c.861G>C p.E287D | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.824); catalogued as COSV57595443; called by muse, mutect2, varscan2
- BATF | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99708816; called by muse, mutect2, varscan2
- BATF3 | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); catalogued as COSV99695962; called by muse, mutect2, varscan2
- BIRC6 | c.13921C>T p.P4641S | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.996); catalogued as COSV101428224; called by muse, mutect2, varscan2
- BMP1 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs762194330, COSV60480157; called by mutect2, varscan2
- BRINP2 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV64178002; called by muse, mutect2, varscan2
- BRPF3 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60207447, COSV60210629; called by muse, varscan2
- C10orf99 | c.71-1G>A p.X24_splice | Splice Site (SNP) | VAF 18/46 reads (39%) | catalogued as rs780233448, COSV64532008; called by muse, mutect2, varscan2
- C1S | c.1680G>A p.M560I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV61071123; called by muse, mutect2, varscan2
- C1orf87 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs762612884, COSV64596931; called by muse, mutect2
- C2CD2 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV61599733; called by muse, mutect2, varscan2
- C3 | c.4007G>A p.G1336E | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55574475, COSV55580978; called by muse, mutect2, varscan2
- C3orf22 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs372125033; called by muse, mutect2, varscan2
- C6orf15 | c.202A>G p.R68G | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV52537806, COSV52538551; called by muse, mutect2, varscan2
- C9orf152 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1205656530, COSV68762701; called by mutect2, varscan2
- CABIN1 | c.4040C>T p.S1347F | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54082965; called by muse, mutect2, varscan2
- CACNB2 | c.251C>T p.S84F (on ENST00000324631 / NM_201596.3; = p.S29F on NM_000724.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs777712736, COSV56612745; called by muse, mutect2, varscan2
- CACNB2 | c.712G>A p.D238N (on ENST00000324631 / NM_201596.3; = p.D183N on NM_000724.4) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.772); catalogued as COSV56629615; called by mutect2, varscan2
- CACNG7 | c.325T>C p.F109L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV55814914; called by muse, varscan2
- CAND1 | c.2198C>T p.S733F | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV73389648; called by muse, mutect2, varscan2
- CAPN11 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67237575; called by muse, mutect2, varscan2
- CAPN13 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 68/189 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV54431761; called by muse, mutect2, varscan2
- CARMIL1 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV61518796; called by muse, mutect2, varscan2
- CASR | c.1681C>T p.R561C (on ENST00000490131; = p.R638C on NM_000388.4) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1185593894, COSV56138364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASZ1 | c.2435C>T p.S812F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV59736719; called by muse, mutect2, varscan2
- CATSPERB | c.3223G>A p.A1075T | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as COSV56424055; called by muse, mutect2, varscan2
- CCBE1 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769574856, COSV67949710; called by muse, mutect2, varscan2
- CCDC7 | c.1454+1G>A p.X485_splice | Splice Site (SNP) | VAF 13/25 reads (52%) | catalogued as COSV99511546; called by muse, mutect2, varscan2
- CCDC93 | c.1753A>T p.K585* | Nonsense Mutation (SNP) | VAF 81/214 reads (38%) | catalogued as COSV60121798; called by muse, mutect2, varscan2
- CCNA1 | c.1363C>T p.L455F | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs572634475, COSV55220153; called by muse, mutect2, varscan2
- CD14 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as COSV57370909; called by muse, mutect2, varscan2
- CDH8 | c.1416G>A p.R472= | Splice Region (SNP) | VAF 4/14 reads (29%) | catalogued as COSV54872649; called by muse, mutect2, varscan2
- CDH8 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868797991, COSV100181473, COSV54872659; called by muse, mutect2, varscan2
- CEACAM5 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55752618; called by muse, mutect2, varscan2
- CELSR1 | c.7117C>T p.P2373S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV53092072; called by muse, mutect2, varscan2
- CEMIP | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as COSV99586640; called by muse, mutect2, varscan2
- CETP | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 111/339 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs371233223, COSV52364119; called by muse, mutect2, varscan2
- CFAP157 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV58853372; called by muse, mutect2, varscan2
- CFAP46 | c.7441G>A p.G2481R | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54153658; called by muse, mutect2, varscan2
- CFAP47 | c.2533C>T p.Q845* | Nonsense Mutation (SNP) | VAF 24/50 reads (48%) | catalogued as COSV52885089; called by muse, varscan2
- CFAP52 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs767415440, COSV55345633; called by mutect2, varscan2
- CFAP65 | c.272C>T p.S91F (on ENST00000341552 / NM_194302.4; = p.S26F on NM_152389.4) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.563); catalogued as rs1421110668, COSV55390606; called by muse, varscan2
- CFAP70 | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60283919; called by muse, mutect2, varscan2
- CHD4 | c.1945C>T p.Q649* (on ENST00000357008 / NM_001363606.2; = p.Q662* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 17/138 reads (12%) | catalogued as COSV58902889; called by muse, mutect2, varscan2
- CISH | c.440G>A p.R147K (on ENST00000348721 / NM_145071.4; = p.R164K on NM_013324.6) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.035); catalogued as COSV62295007; called by muse, mutect2, varscan2
- CLCN2 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV55599877; called by muse, mutect2, varscan2
- CLVS1 | c.767A>G p.N256S | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.029); catalogued as COSV57976636; called by muse, mutect2, varscan2
- CNGA3 | c.1249A>C p.I417L | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV55624992; called by muse, mutect2, varscan2
- CNKSR2 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs746835614, COSV54258098; called by muse, mutect2, varscan2
- CNTN4 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.924); catalogued as rs1349406131, COSV61869503, COSV61881190; called by muse, mutect2, varscan2
- CNTNAP5 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as rs1447158750, COSV70472787; called by muse, mutect2, varscan2
- COL1A1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as CD152796, COSV56806069; called by muse, mutect2, varscan2
- COL3A1 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58590022; called by muse, mutect2, varscan2
- COL4A3 | c.1864G>A p.G622R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV67416903; called by muse, mutect2, varscan2
- COL4A3 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101170225, COSV67414765; called by muse, mutect2, varscan2
- COL4A5 | c.4753C>T p.H1585Y | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV60363392; called by muse, mutect2, varscan2
- COL4A6 | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57868661; called by muse, mutect2, varscan2
- COL5A1 | c.4702C>T p.P1568S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs756837325, COSV65670036; called by muse, mutect2, varscan2
- CPA4 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55983603, COSV55984811; called by muse, mutect2, varscan2
- CPT1A | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); catalogued as rs146533704; called by muse, mutect2, varscan2
- CR1 | c.5870G>A p.R1957K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.254); catalogued as COSV65458971; called by muse, mutect2, varscan2
- CSF1 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.138); catalogued as COSV60033627; called by muse, mutect2, varscan2
- CSF2RA | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 76/321 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV62625033; called by muse, mutect2, varscan2
- CSHL1 | c.613G>A p.E205K (on ENST00000309894 / NM_022581.3; = p.E111K on NM_001318.4) | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); catalogued as rs775171157, COSV51987773; called by muse, mutect2, varscan2
- CSMD1 | c.7865C>T p.S2622L (on ENST00000520002; = p.S2621L on NM_033225.6) | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377667100, COSV59317265; called by muse, mutect2, varscan2
- CSMD1 | c.1166C>T p.T389I (on ENST00000520002; = p.T388I on NM_033225.6) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV68214019; called by muse, mutect2, varscan2
- CSMD1 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.919); catalogued as COSV68205737; called by muse, mutect2, varscan2
- CSMD3 | c.7927A>T p.I2643L (on ENST00000297405 / NM_001363185.1; = p.I2539L on NM_052900.3) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV52204935; called by muse, mutect2
- CSMD3 | c.7024G>A p.G2342R (on ENST00000297405 / NM_001363185.1; = p.G2238R on NM_052900.3) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52204955; called by muse, mutect2, varscan2
- CST11 | c.317A>T p.E106V | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV65440837; called by muse, mutect2, varscan2
- CTAGE6 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs780977234, COSV101417811, COSV101417842; called by muse, mutect2
- CTBP2 | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV58334827; called by muse, mutect2, varscan2
- CTNNBL1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs774420988, COSV63744618; called by muse, mutect2, varscan2
- CTNND2 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs766971877, COSV58895109; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs771312411, COSV54745046; called by muse, mutect2, varscan2
- CWF19L2 | c.2653C>T p.P885S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as COSV56513918; called by muse, mutect2, varscan2
- CWH43 | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.557); catalogued as COSV56939695; called by muse, mutect2, varscan2
- CWH43 | c.1062G>A p.G354= | Splice Region (SNP) | VAF 14/31 reads (45%) | catalogued as COSV99893319; called by muse, mutect2, varscan2
- CYP11A1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as rs370465035, COSV99166074; called by muse, mutect2, varscan2
- CYP2F1 | c.273G>T p.Q91H | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.878); catalogued as COSV58527863; called by muse, mutect2, varscan2
- DACH1 | c.1742C>T p.S581F (on ENST00000619232 / NM_001366712.1; = p.S327F on NM_004392.6) | Missense Mutation (SNP) | VAF 82/225 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV100499256, COSV57503837; called by muse, mutect2, varscan2
- DAGLA | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57196948; called by muse, mutect2, varscan2
- DCAF16 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.001); catalogued as COSV66384244; called by muse, mutect2, varscan2
- DCC | c.3398G>A p.R1133Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs753074420, COSV71433463, COSV71436709; called by mutect2, varscan2
- DDC | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV63565580, COSV63568253; called by muse, mutect2, varscan2
- DDX54 | c.2404C>T p.R802C | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs1004491131, COSV58374223; called by muse, mutect2, varscan2
- DENND2C | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs867718423, COSV67921647; called by muse, mutect2, varscan2
- DEPDC4 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.046); catalogued as COSV54553764; called by muse, mutect2, varscan2
- DIAPH2 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1472012351, COSV61273347; called by muse, mutect2, varscan2
- DLEC1 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57300948; called by muse, mutect2, varscan2
- DNAH11 | c.10536G>A p.M3512I | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs759819257, COSV60960070; called by muse, mutect2, varscan2
- DNAH2 | c.6094C>T p.P2032S | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66720706; called by muse, mutect2, varscan2
- DNAH5 | c.9568G>A p.G3190R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV54231271; called by muse, mutect2, varscan2
- DNAH9 | c.6104C>T p.S2035F | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747320293, COSV52354136; called by muse, mutect2, varscan2
- DNAJB12 | c.709C>T p.L237F (on ENST00000338820; = p.L203F on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58760645; called by muse, mutect2
- DNAJC6 | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as COSV54776543; called by muse, varscan2
- DNASE2 | c.217G>C p.G73R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV53435211; called by muse, mutect2, varscan2
- DNER | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs267599247, COSV59164458; called by muse, mutect2, varscan2
- DOCK2 | c.3173A>G p.K1058R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.98); catalogued as COSV56963361, COSV56971995; called by mutect2, varscan2
- DOK2 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.498); catalogued as COSV52388890, COSV99374563; called by muse, mutect2, varscan2
- DRC7 | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751256275, COSV61055489; called by muse, mutect2, varscan2
- DSCAML1 | c.3836G>A p.G1279E (on ENST00000321322; = p.G1219E on NM_020693.4) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58392768; called by muse, mutect2, varscan2
- DSG1 | c.2798T>A p.M933K | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV57136213; called by muse, mutect2, varscan2
- DYNC1I1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.42); catalogued as COSV61462579; called by muse, mutect2, varscan2
- ECE1 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); catalogued as rs1227922518, COSV51665704; called by muse, mutect2, varscan2
- EFTUD2 | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV68183396; called by muse, mutect2, varscan2
- EGFLAM | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.011); catalogued as COSV59305266; called by muse, mutect2, varscan2
- EGLN3 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as COSV51654983; called by muse, mutect2, varscan2
- EGR2 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.296); catalogued as COSV54347227; called by mutect2, varscan2
- ELF4 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV57453019; called by muse, mutect2, varscan2
- EML3 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53882939, COSV53883848; called by muse, mutect2, varscan2
- EMSY | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58261277; called by muse, mutect2, varscan2
- EP400 | c.5554C>T p.P1852S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as rs934777503, COSV57775138; called by muse, mutect2
- EPB41L3 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59456536; called by muse, mutect2, varscan2
- EPHA3 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV60699220, COSV60706097; called by muse, mutect2, varscan2
- ERICH3 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as COSV58609254; called by muse, mutect2, varscan2
- ERICH6 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV55801125; called by mutect2, varscan2
- EYA1 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV58164905, COSV58167886; called by muse, mutect2, varscan2
- FAM153A | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.486); catalogued as COSV62362303; called by muse, mutect2, varscan2
- FAM153B | c.688G>A p.E230K (on ENST00000253490; = p.E153K on NM_001265615.1) | Missense Mutation (SNP) | VAF 65/393 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.908); catalogued as rs772754788, COSV53686847; called by muse, mutect2, varscan2
- FAM221B | c.494A>C p.Q165P | Missense Mutation (SNP) | VAF 71/226 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.187); catalogued as COSV65074522; called by muse, mutect2, varscan2
- FAM47C | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV63727257; called by muse, varscan2
- FAM83B | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs765150070, COSV60919408; called by mutect2, varscan2
- FAM83B | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs749949321, COSV60922941; called by mutect2, varscan2
- FASTKD5 | c.845T>C p.V282A | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV53906559; called by muse, mutect2, varscan2
- FAT2 | c.4468G>A p.D1490N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.713); catalogued as COSV55821443; called by muse, mutect2, varscan2
- FAT4 | c.6625G>A p.G2209S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58688338; called by muse, mutect2, varscan2
- FAT4 | c.10351G>A p.E3451K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.992); catalogued as COSV58678810; called by mutect2, varscan2
- FATE1 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.722); catalogued as COSV64848910, COSV64849232; called by muse, mutect2, varscan2
- FBN3 | c.4631C>T p.T1544I | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.824); catalogued as COSV54463301; called by muse, mutect2, varscan2
- FBN3 | c.1879G>A p.G627S | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54463316; called by muse, mutect2, varscan2
- FBXO47 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65241976; called by muse, mutect2, varscan2
- FCRL5 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV62515532; called by muse, varscan2
- FER1L5 | c.4186A>T p.K1396* (on ENST00000623019; = p.K1369* on NM_001293083.2) | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV67606292; called by mutect2, varscan2
- FERMT3 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs1034960775, COSV99656535; called by muse, mutect2, varscan2
- FGD6 | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); catalogued as COSV59692589; called by muse, mutect2, varscan2
- FITM1 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.036); catalogued as rs776470418, COSV52824487; called by muse, mutect2, varscan2
- FLG | c.11545G>A p.E3849K | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV64242921; called by muse, mutect2, varscan2
- FLNC | c.4637G>A p.G1546D | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427917546, COSV57957340; called by muse, mutect2, varscan2
- FLRT2 | c.91T>G p.S31A | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV58143464, COSV58147641; called by muse, mutect2, varscan2
- FMO2 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV52946669; called by muse, varscan2
- FOCAD | c.5051G>A p.W1684* | Nonsense Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as rs1461599092, COSV58101031; called by muse, varscan2
- FOXA3 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56216369; called by muse, mutect2, varscan2
- FOXL2NB | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV57727512; called by muse, mutect2, varscan2
- FREM2 | c.7708C>G p.P2570A | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.562); catalogued as COSV54840640; called by muse, mutect2, varscan2
- FST | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV56814858, COSV56815961; called by muse, mutect2, varscan2
- FSTL4 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1409501536, COSV54773789; called by muse, mutect2, varscan2
- FXR1 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV59763583; called by muse, mutect2, varscan2
- GABPB2 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV64460991; called by muse, mutect2, varscan2
- GABRA3 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1405808499, COSV64795525; called by muse, mutect2, varscan2
- GABRA6 | c.1321C>T p.L441F | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754535981, COSV50883381, COSV50889278; called by muse, mutect2, varscan2
- GABRB1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs867326305, COSV54980730; called by muse, mutect2, varscan2
- GBP2 | c.1675C>T p.L559F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as COSV65069623; called by muse, mutect2, varscan2
- GEMIN8 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 65/92 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60550769; called by muse, mutect2, varscan2
- GFPT2 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53809311; called by muse, mutect2, varscan2
- GIMAP2 | c.158G>A p.G53D | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as COSV56235512; called by muse, mutect2, varscan2
- GIMAP4 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.453); catalogued as COSV55432937; called by muse, varscan2
- GIMAP8 | c.1658G>A p.G553E | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV56231987; called by muse, mutect2, varscan2
- GIT2 | c.1767G>T p.E589D (on ENST00000355312 / NM_057169.5; = p.E511D on NM_014776.5) | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV58081501; called by mutect2, varscan2
- GJA1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1189422011, COSV56996867, COSV56997288; called by muse, mutect2, varscan2
- GJA8 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53789179; called by muse, mutect2, varscan2
- GLP2R | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs564939715, COSV52325804; called by muse, mutect2, varscan2
- GLYAT | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs1374029986, COSV53539582; called by muse, mutect2, varscan2
- GPC5 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.339); catalogued as rs777802113, COSV65582090; called by muse, mutect2, varscan2
- GPR141 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs150971296; called by muse, mutect2, varscan2
- GPRC6A | c.2573C>T p.S858F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV59953563; called by mutect2, varscan2
- GRIK3 | c.2174G>A p.G725D | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66140970, COSV66141889; called by muse, varscan2
- GRM3 | c.1280G>A p.G427E | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64473176; called by muse, mutect2, varscan2
- GSDMC | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs759624672, COSV52696137; called by muse, mutect2, varscan2
- GSS | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs780432814, COSV53813178; called by muse, mutect2, varscan2
- GUCY2C | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs192356391, COSV53788241; called by muse, mutect2, varscan2
- HAPLN1 | c.315T>A p.Y105* | Nonsense Mutation (SNP) | VAF 23/96 reads (24%) | catalogued as COSV57148716; called by muse, mutect2, varscan2
- HDAC7 | c.338C>T p.P113L (on ENST00000427332; = p.P152L on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/343 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.046); catalogued as COSV50370589; called by muse, mutect2, varscan2
- HDC | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367618872, COSV51070116; called by muse, mutect2, varscan2
- HECTD4 | c.11290G>T p.V3764L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); catalogued as COSV66393497; called by muse, mutect2, varscan2
- HELZ2 | c.278+1G>A p.X93_splice | Splice Site (SNP) | VAF 13/28 reads (46%) | catalogued as rs1366319785, COSV64409839; called by muse, mutect2, varscan2
- HLA-DRA | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV66622792, COSV66622814; called by muse, mutect2, varscan2
- HNF1A | c.479C>A p.A160D | Missense Mutation (SNP) | VAF 46/363 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV57463092; called by muse, mutect2, varscan2
- HNF4A | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 45/235 reads (19%) | catalogued as CM133293, COSV57384251; called by muse, mutect2, varscan2
- HNRNPL | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.262); catalogued as COSV55493208; called by muse, mutect2, varscan2
- HPGDS | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54774410; called by muse, mutect2, varscan2
- HSD11B1 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1268242198, COSV54827934; called by muse, mutect2, varscan2
- HSH2D | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs764207746, COSV53738329, COSV99507103, COSV99507180; called by muse, mutect2, varscan2
- ICE1 | c.2530C>T p.P844S | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.468); catalogued as COSV56826804; called by muse, mutect2, varscan2
- IDO2 | c.388C>T p.H130Y (on ENST00000389060; = p.H143Y on NM_194294.2) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.773); catalogued as COSV58426116; called by muse, mutect2
- IGSF10 | c.5996G>A p.G1999E | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747787349, COSV56382046; called by muse, mutect2
- IGSF10 | c.1921G>A p.G641S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56786557; called by mutect2, varscan2
- IL1RAPL2 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61146324; called by muse, mutect2, varscan2
- ILDR1 | c.896C>T p.A299V (on ENST00000344209 / NM_001199799.2; = p.A255V on NM_175924.4) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs201919360, COSV56550743; called by muse, mutect2, varscan2
- IMPDH2 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100455022; called by muse, mutect2, varscan2
- INAVA | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV66256799; called by muse, varscan2
- INHBA | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs867739441, COSV54222147; called by muse, varscan2
- INHBA | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.405); catalogued as COSV54222154; called by muse, varscan2
- INO80E | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54229100; called by muse, mutect2, varscan2
- IPP | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63432807; called by muse, mutect2, varscan2
- ITGA2B | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as rs779592785, COSV52233041; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITPR1 | c.6608G>A p.R2203Q (on ENST00000354582; = p.R2148Q on NM_002222.7) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs781761068, COSV56982734; called by mutect2, varscan2
- IWS1 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV54869169; called by muse, mutect2, varscan2
- JPH1 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as rs1181493460, COSV60611721; called by muse, varscan2
- KALRN | c.5861G>A p.G1954D (on ENST00000360013 / NM_001024660.4; = p.G257D on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV52258351; called by muse, mutect2, varscan2
- KAT2A | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs781999975, COSV56791288; called by muse, mutect2, varscan2
- KCNB2 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV73050741; called by muse, mutect2, varscan2
- KCNH1 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55072823; called by muse, mutect2, varscan2
- KCNQ3 | c.2171G>A p.G724E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1183228440, COSV66466929; called by muse, mutect2, varscan2
- KCNT1 | c.1005G>A p.M335I (on ENST00000488444; = p.M354I on NM_020822.3) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.27); catalogued as COSV53703209; called by muse, varscan2
- KIAA1217 | c.1310A>G p.N437S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as COSV100287316, COSV56817917; called by muse, mutect2, varscan2
- KIAA1217 | c.2309G>A p.G770E | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56817930; called by muse, mutect2, varscan2
- KIF14 | c.4492A>T p.N1498Y | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV66262137; called by muse, mutect2, varscan2
- KIF21A | c.3953C>T p.S1318F (on ENST00000361418 / NM_001378440.1; = p.S1305F on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1485764024, COSV62772644; called by muse, mutect2
- KIF5A | c.2993G>A p.G998E | Missense Mutation (SNP) | VAF 117/271 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV54054975; called by muse, mutect2, varscan2
- KIR3DL1 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); catalogued as rs746815710, COSV100428568; called by muse, mutect2, varscan2
- KLHL1 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV64773595, COSV64774104; called by muse, mutect2, varscan2
- KLHL23 | c.617A>G p.K206R | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as COSV55867589; called by muse, mutect2, varscan2
- KMT2D | c.2678C>T p.P893L | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV56449952; called by muse, mutect2, varscan2
- KRT10 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1319705744, COSV54090075; called by muse, mutect2, varscan2
- KRTAP5-5 | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.144); catalogued as rs1201725024, COSV68785080; called by muse, varscan2
- KRTAP5-7 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); catalogued as rs772783550, COSV68325337; called by muse, mutect2, varscan2
- LAMA2 | c.3571G>A p.E1191K | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.416); catalogued as COSV70344499, COSV70351713; called by muse, mutect2, varscan2
- LAMB2 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.187); catalogued as rs1419321435, COSV59734375; called by muse, mutect2, varscan2
- LILRA4 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV52492620; called by muse, mutect2, varscan2
- LIPC | c.1232G>A p.G411D | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54423470; called by muse, mutect2, varscan2
- LONRF2 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66540974; called by muse, mutect2, varscan2
- LOXL2 | c.502T>C p.F168L | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV66691850; called by muse, mutect2, varscan2
- LRCH4 | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV56166395; called by muse, mutect2, varscan2
- LRP2 | c.11768C>T p.P3923L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as rs776977042, COSV55557369; called by muse, mutect2, varscan2
- LRP2 | c.7916G>A p.G2639E | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV55557375; called by muse, mutect2, varscan2
- LRRC4C | c.1386G>A p.M462I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV99538012; called by muse, mutect2, varscan2
- LRRC7 | c.128G>A p.R43Q (on ENST00000651989 / NM_001370785.2; = p.R10Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747077838, COSV50418241, COSV99230272; called by mutect2, varscan2
- MAB21L3 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 94/230 reads (41%) | catalogued as COSV65674000; called by muse, mutect2, varscan2
- MAGEE2 | c.1543A>G p.T515A | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV64897885; called by muse, mutect2, varscan2
- MAP3K3 | c.166C>G p.R56G | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62280937; called by muse, mutect2, varscan2
- MAP3K5 | c.1972G>A p.G658R | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.909); catalogued as rs1305339619, COSV62889681; called by muse, mutect2
- MARCHF7 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52029189, COSV99373447; called by muse, mutect2, varscan2
- MATN1 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.333); catalogued as rs749994405, COSV65650769; called by muse, mutect2, varscan2
- MCF2L2 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV61055025; called by muse, mutect2, varscan2
- MCM3AP | c.2621T>A p.F874Y | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52440829; called by muse, mutect2, varscan2
- MCOLN1 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as rs765577483, COSV51174098; called by muse, mutect2, varscan2
- MDFIC | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs748686843, COSV57564452; called by muse, mutect2, varscan2
- MDFIC | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 24/68 reads (35%) | catalogued as COSV57564458; called by muse, mutect2, varscan2
- MERTK | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54930470; called by muse, varscan2
- METTL2B | c.265T>C p.F89L | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52309212; called by muse, mutect2, varscan2
- MGAM | c.3059C>T p.S1020F | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV72074432, COSV72075227; called by muse, mutect2, varscan2
- MIA2 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as COSV54483288, COSV54484004; called by muse, mutect2, varscan2
- MOG | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV65321254; called by muse, mutect2, varscan2
- MPO | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV51859749, COSV51863324, COSV99228818; called by muse, mutect2, varscan2
- MRGPRX1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | catalogued as COSV57107719; called by muse, mutect2, varscan2
- MRPL54 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.652); catalogued as COSV57462859; called by muse, mutect2, varscan2
- MTCL1 | c.1138C>T p.R380W (on ENST00000306329 / NM_001378206.1; = p.R20W on NM_015210.4) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60406272; called by muse, mutect2, varscan2
- MUC16 | c.37588C>T p.P12530S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.763); catalogued as COSV67461683; called by muse, mutect2, varscan2
- MUC16 | c.28055G>A p.R9352K | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.161); catalogued as COSV67472359; called by muse, mutect2, varscan2
- MUC16 | c.17551C>T p.P5851S | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); catalogued as rs267605800, COSV67460962; called by muse, mutect2, varscan2
- MUC16 | c.7114G>A p.D2372N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs867466995, COSV67460769; called by muse, mutect2, varscan2
- MUTYH | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs376790729, CM077609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYCBPAP | c.1540C>T p.H514Y | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV60408657; called by muse, varscan2
- MYF6 | c.620G>A p.S207N | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as COSV99952771; called by muse, mutect2, varscan2
- MYF6 | c.621T>A p.S207R | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV99952772; called by muse, mutect2, varscan2
- MYH1 | c.4380G>A p.W1460* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as rs1203438599, COSV56850091; called by muse, mutect2, varscan2
- MYH2 | c.4399G>A p.E1467K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV55440115; called by mutect2, varscan2
- MYH6 | c.2542G>A p.E848K | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1297856283, COSV62451594; called by muse, mutect2, varscan2
- MYO1F | c.66G>A p.M22I | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57796075; called by muse, mutect2, varscan2
- MYOCD | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs757539762, COSV58505151; called by muse, mutect2, varscan2
- MYOM3 | c.1865G>A p.W622* | Nonsense Mutation (SNP) | VAF 88/245 reads (36%) | catalogued as rs747476677, COSV58395065; called by muse, mutect2, varscan2
- NCAM1 | c.1463A>G p.N488S (on ENST00000316851 / NM_181351.5; = p.N478S on NM_000615.7) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100377991, COSV57518097; called by muse, mutect2, varscan2
- NCOA1 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs770272724, COSV56045897; called by muse, mutect2, varscan2
- NEBL | c.2999G>A p.G1000E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65803553; called by muse, varscan2
- NEBL | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.151); catalogued as rs774294999, COSV65802298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NECTIN4 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as COSV63512975; called by muse, mutect2, varscan2
- NEFM | c.2518G>A p.D840N | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as COSV55332642; called by muse, mutect2, varscan2
- NFASC | c.1649C>T p.S550F (on ENST00000339876 / NM_001378329.1; = p.S561F on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV58367723; called by muse, mutect2, varscan2
- NFATC1 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV53701987; called by muse, mutect2, varscan2
- NFXL1 | c.425T>C p.L142S | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV61199341; called by muse, mutect2
- NIPBL | c.8069G>A p.R2690Q | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.551); catalogued as rs761090361, COSV56953739; called by muse, mutect2, varscan2
- NLGN4X | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV52011278; called by muse, mutect2, varscan2
- NLRP10 | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as COSV60780658; called by muse, mutect2, varscan2
- NLRP11 | c.2317C>T p.P773S | Missense Mutation (SNP) | VAF 131/387 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV64087751; called by muse, mutect2, varscan2
- NLRP2 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV54756242; called by muse, mutect2, varscan2
- NLRP8 | c.2382-1G>A p.X794_splice | Splice Site (SNP) | VAF 58/198 reads (29%) | catalogued as COSV52588823; called by muse, mutect2, varscan2
- NOD2 | c.3076G>A p.E1026K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56051813; called by muse, mutect2, varscan2
- NOS1 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.145); catalogued as COSV57614282; called by muse, mutect2, varscan2
- NOTCH2NLA | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV61250363; called by mutect2, varscan2
- NR1H4 | c.698C>T p.T233I (on ENST00000551379 / NM_001206993.2; = p.T219I on NM_005123.4) | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.056); catalogued as COSV51852986; called by muse, mutect2, varscan2
- NRP2 | c.1498G>A p.G500S | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs745533260, COSV55929738, COSV55931644; called by muse, mutect2, varscan2
- NTN4 | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.068); catalogued as COSV59220503; called by muse, mutect2, varscan2
- NUP98 | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 77/195 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV61433058; called by muse, mutect2, varscan2
- OR10A6 | c.137T>C p.I46T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs377657725, COSV59165290; called by muse, mutect2, varscan2
- OR10J5 | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58385072; called by muse, mutect2, varscan2
- OR13C3 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as rs375714407; called by muse, mutect2, varscan2
- OR14C36 | c.808C>G p.L270V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV58601607, COSV58601710; called by muse, mutect2, varscan2
- OR14I1 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1206594083, COSV61199821; called by muse, mutect2, varscan2
- OR2B3 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65850722, COSV65851000; called by muse, mutect2, varscan2
- OR4A16 | c.571T>C p.Y191H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.248); catalogued as COSV59043502; called by muse, mutect2, varscan2
- OR4C13 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782667631, COSV73648787, COSV73648916; called by muse, mutect2, varscan2
- OR4C13 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as rs190982976, COSV73648668; called by muse, varscan2
- OR4C15 | c.1010C>T p.P337L (on ENST00000314644; = p.P283L on NM_001001920.2) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs774055903, COSV58953325, COSV58954238, COSV58955502; called by mutect2, varscan2
- OR51E1 | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67810186; called by muse, mutect2, varscan2
- OR52H1 | c.94C>T p.P32S (on ENST00000322653; = p.P38S on NM_001005289.1) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs959225114, COSV59505567; called by muse, mutect2, varscan2
- OR52J3 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs779465901, COSV66746564; called by muse, mutect2, varscan2
- OR52N1 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as COSV57693492; called by muse, mutect2, varscan2
- OR56A4 | c.839T>G p.V280G | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58110484; called by muse, mutect2, varscan2
- OR56B4 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | catalogued as COSV57203692; called by muse, mutect2, varscan2
- OR5B17 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs868743937, COSV62159822; called by muse, mutect2, varscan2
- OR5D13 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs150275540; called by muse, mutect2, varscan2
- OR5F1 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); catalogued as COSV53546919, COSV53548309, COSV53548537; called by muse, mutect2, varscan2
- OR5M1 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV73202093; called by mutect2, varscan2
- OR5T1 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs149057096; called by muse, mutect2, varscan2
- OR6A2 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs151066337; called by mutect2, varscan2
- OR6B1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); catalogued as COSV68770257; called by muse, mutect2, varscan2
- OR6V1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 80/234 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs867782093, COSV69237344; called by muse, varscan2
- OTOP1 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV56393961; called by muse, mutect2, varscan2
- P4HA3 | c.1468-1G>A p.X490_splice | Splice Site (SNP) | VAF 34/68 reads (50%) | catalogued as COSV100525690; called by muse, mutect2, varscan2
- PANK4 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779324364, COSV65866933, COSV65867222; called by muse, mutect2, varscan2
- PAPPA2 | c.2992C>T p.P998S | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV62799833; called by muse, mutect2, varscan2
- PARM1 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1370828994, COSV56654648; called by muse, mutect2, varscan2
- PCDH19 | c.3118G>A p.D1040N (on ENST00000373034 / NM_001184880.2; = p.D992N on NM_020766.3) | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs764683848, COSV55261844; called by muse, mutect2, varscan2
- PCDHA11 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1168032645, COSV56510878; called by muse, mutect2, varscan2
- PCDHA12 | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as rs267600400, COSV56510900; called by muse, mutect2, varscan2
- PCDHA2 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.945); catalogued as COSV65367662; called by muse, mutect2, varscan2
- PCDHA8 | c.1229A>T p.D410V | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV65337841; called by muse, mutect2, varscan2
- PCDHB1 | c.2045G>A p.R682K | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV60631431; called by muse, mutect2, varscan2
- PCDHB6 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV50701310; called by muse, mutect2, varscan2
- PCDHB7 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV50766710; called by muse, mutect2, varscan2
- PCK2 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as rs769413915, COSV53747839; called by muse, mutect2, varscan2
- PCLO | c.8149G>A p.E2717K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV61640362; called by muse, mutect2, varscan2
- PCLO | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.088); catalogued as COSV61640377; called by muse, mutect2, varscan2
- PCNX3 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV58420164; called by muse, mutect2, varscan2
- PDZRN4 | c.2661G>A p.M887I (on ENST00000402685 / NM_001164595.2; = p.M629I on NM_013377.4) | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs750712050, COSV54204618; called by muse, varscan2
- PHF12 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52019785; called by muse, mutect2, varscan2
- PHKA1 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59807003; called by muse, mutect2, varscan2
- PHKG1 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.383); catalogued as rs1245157298, COSV51916792; called by muse, mutect2, varscan2
- PHKG1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as COSV99305079; called by muse, mutect2, varscan2
- PHTF2 | c.1298C>T p.P433L (on ENST00000248550 / NM_001366089.1; = p.P395L on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV50328388; called by muse, mutect2, varscan2
- PI16 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs751280961, COSV65448281; called by muse, mutect2, varscan2
- PIEZO2 | c.6852-1G>A p.X2284_splice | Splice Site (SNP) | VAF 8/29 reads (28%) | catalogued as COSV53290543; called by muse, mutect2, varscan2
- PIK3C2G | c.2197C>T p.P733S (on ENST00000676171; = p.P692S on NM_004570.5) | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV56798959, COSV56803001; called by muse, mutect2, varscan2
- PITPNB | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58061653; called by muse, mutect2, varscan2
- PITPNM1 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as COSV62708465; called by muse, mutect2, varscan2
- PIWIL1 | c.1364G>A p.R455K | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV55347743, COSV55353192; called by muse, mutect2, varscan2
- PKHD1L1 | c.3571G>A p.E1191K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs868566715, COSV101006684, COSV65745011; called by muse, mutect2, varscan2
- PKHD1L1 | c.4948G>A p.E1650K | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as rs887350500, COSV65745017; called by muse, varscan2
- PKHD1L1 | c.5273C>T p.S1758F | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV65736818, COSV65745021; called by muse, mutect2, varscan2
- PKIB | c.68G>A p.R23K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99236299; called by muse, mutect2, varscan2
- PKP1 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751008697, COSV99825252; called by mutect2, varscan2
- PLCG2 | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63870796; called by muse, mutect2, varscan2
- PLCH1 | c.3970G>A p.D1324N (on ENST00000340059 / NM_001130960.2; = p.D1316N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV58200364; called by muse, mutect2, varscan2
- PLCL2 | c.656C>T p.S219F (on ENST00000615277 / NM_001144382.2; = p.S93F on NM_015184.5) | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67622713; called by muse, varscan2
- PLEKHG4 | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58573259; called by muse, mutect2, varscan2
- PLIN3 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55735581; called by muse, mutect2, varscan2
- PNLIP | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1250314817, COSV65039564; called by muse, mutect2, varscan2
- POLR2A | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV59492906; called by muse, mutect2, varscan2
- POM121L12 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as rs1483169703, COSV68692710; called by muse, mutect2
- POM121L12 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.045); catalogued as rs763758598, COSV68692885; called by muse, mutect2, varscan2
- PPIL2 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 84/223 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1279034844, COSV58605497; called by muse, mutect2, varscan2
- PPP1R13B | c.3260G>A p.R1087Q | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52452588; called by muse, mutect2, varscan2
- PPP1R9A | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV56896410; called by muse, mutect2, varscan2
- PPP6R1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV69799921; called by muse, mutect2, varscan2
- PRAMEF7 | c.1274G>T p.C425F | Missense Mutation (SNP) | VAF 29/354 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.706); catalogued as rs778996785, COSV58278471; called by muse, mutect2
- PRDM2 | c.2344C>T p.P782S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs376386881, COSV52448685; called by muse, mutect2, varscan2
- PRDM2 | c.3709C>T p.P1237S | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV52448693; called by muse, mutect2, varscan2
- PRDM9 | c.782G>A p.W261* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV57005665; called by muse, mutect2, varscan2
- PRIMPOL | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59249122; called by muse, mutect2, varscan2
- PRKACG | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55249791, COSV55257466; called by muse, mutect2, varscan2
- PRKAR1B | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV64317758; called by muse, mutect2, varscan2
- PRKCH | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs746043886, COSV60646852; called by mutect2, varscan2
- PRMT2 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52455706; called by muse, mutect2, varscan2
- PRR12 | c.3341C>T p.P1114L (on ENST00000615927; = p.P1935L on NM_020719.3) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.098); catalogued as COSV69817946; called by muse, mutect2, varscan2
- PRSS35 | c.1135C>T p.H379Y | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV63800707; called by muse, varscan2
- PRUNE2 | c.4898C>T p.S1633F | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV65042572; called by muse, mutect2, varscan2
- PSG9 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 89/339 reads (26%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.973); catalogued as rs768179976, COSV52485575; called by muse, mutect2, varscan2
- PSMC1 | c.488T>G p.L163R | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV54321040; called by muse, mutect2, varscan2
- PTCHD3 | c.2240C>T p.S747F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71256391; called by muse, mutect2, varscan2
- PTPRO | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); catalogued as COSV55503796; called by muse, mutect2
- PTPRT | c.3254G>A p.S1085N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV61972113, COSV61987911; called by muse, mutect2, varscan2
- PTPRT | c.2516C>T p.S839F | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs781621750, COSV61963302; called by muse, mutect2, varscan2
- PWWP3B | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.856); catalogued as COSV100531199; called by muse, mutect2, varscan2
- QPCTL | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1249948706, COSV50004010; called by muse, mutect2, varscan2
- R3HDM1 | c.2161C>T p.Q721* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | catalogued as COSV51526008; called by muse, mutect2, varscan2
- RAB40C | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.959); catalogued as COSV50193863; called by muse, mutect2, varscan2
- RABGAP1 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV58060369; called by muse, mutect2, varscan2
- RAD54B | c.2554C>T p.Q852* | Nonsense Mutation (SNP) | VAF 12/84 reads (14%) | catalogued as COSV60252212; called by muse, mutect2
- RAG2 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV57556283; called by muse, mutect2, varscan2
- RALYL | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs774536609, COSV72819620; called by muse, mutect2, varscan2
- RAPGEF5 | c.422C>T p.P141L (on ENST00000401957 / NM_001367602.2; = p.P444L on NM_012294.5) | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768758592, COSV59782247; called by muse, mutect2, varscan2
- RARRES2 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.935); catalogued as rs377597732; called by muse, mutect2, varscan2
- RASGEF1C | c.1084-1G>A p.X362_splice | Splice Site (SNP) | VAF 12/41 reads (29%) | catalogued as COSV63181307; called by muse, mutect2, varscan2
- RC3H1 | c.700T>C p.F234L | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV51202609, COSV99281129; called by muse, mutect2, varscan2
- RELN | c.3033G>A p.W1011* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV59008157; called by muse, mutect2, varscan2
- REST | c.2759C>T p.S920L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV58361089; called by muse, mutect2, varscan2
- REXO1 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV50079618; called by muse, mutect2, varscan2
- RGS22 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs539219651, COSV62662991; called by muse, mutect2, varscan2
- RHBDF1 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.403); catalogued as rs776719676, COSV99244576; called by muse, mutect2, varscan2
- RHCE | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1053369, COSV53801026; called by mutect2, varscan2
- RMDN1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV52207110; called by muse, mutect2, varscan2
- RNF152 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as COSV57185944; called by muse, mutect2, varscan2
- ROBO1 | c.4490C>T p.S1497F | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV71395464; called by muse, mutect2, varscan2
- ROBO2 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV59915465; called by muse, mutect2
- RP1 | c.4576G>A p.E1526K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV55110547; called by muse, mutect2
- RP1 | c.4846G>A p.E1616K | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs868089931, COSV55115574; called by muse, mutect2, varscan2
- RPAP1 | c.1724A>G p.H575R | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58539935; called by muse, mutect2, varscan2
- RPRD2 | c.3862C>T p.P1288S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.137); catalogued as COSV64820980; called by muse, mutect2, varscan2
- S1PR1 | c.328T>C p.Y110H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59513453; called by muse, varscan2
- SAMD9 | c.4307C>T p.S1436F | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1426433587, COSV66075976; called by muse, mutect2
- SAMD9L | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as COSV59082256; called by muse, mutect2, varscan2
- SCAP | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55562194; called by muse, mutect2, varscan2
- SCN11A | c.3032C>T p.P1011L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV56569601; called by muse, mutect2, varscan2
- SCN1A | c.5279C>T p.S1760F (on ENST00000303395 / NM_001202435.3; = p.S1749F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57672951; called by muse, mutect2, varscan2
- SCN3A | c.1964C>T p.S655F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV51813308; called by muse, mutect2, varscan2
- SCN9A | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV57612703, COSV57629889; called by muse, mutect2, varscan2
- SCNN1B | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 34/129 reads (26%) | catalogued as COSV56305543; called by muse, mutect2, varscan2
- SCUBE2 | c.2116C>T p.P706S (on ENST00000649792 / NM_001367977.2; = p.P551S on NM_001170690.2) | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.077); catalogued as COSV100496606; called by muse, mutect2, varscan2
- SDK1 | c.2599G>A p.G867R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1205197141, COSV67364246; called by muse, mutect2, varscan2
- SEC22A | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV59372228; called by muse, mutect2, varscan2
- SEH1L | c.805C>T p.H269Y | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.233); catalogued as COSV50816822; called by mutect2, varscan2
- SERPINB3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369196968; called by muse, mutect2, varscan2
- SERTM1 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV100171334; called by muse, mutect2, varscan2
- SEZ6 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV57979776; called by muse, mutect2, varscan2
- SGCG | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54561886; called by muse, mutect2, varscan2
- SGK1 | c.417+1G>A p.X139_splice | Splice Site (SNP) | VAF 9/61 reads (15%) | catalogued as COSV99398171; called by muse, mutect2, varscan2
- SGK1 | c.417G>A p.E139= | Splice Region (SNP) | VAF 10/63 reads (16%) | catalogued as COSV99398182; called by muse, mutect2, varscan2
- SH3RF2 | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV63039410; called by muse, mutect2, varscan2
- SHBG | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52647027; called by muse, mutect2, varscan2
- SI | c.3421G>A p.G1141S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as rs368953032; called by muse, mutect2, varscan2
- SIGLEC11 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as rs759718197, COSV70222026; called by muse, mutect2, varscan2
- SIGLEC7 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as COSV58315928; called by muse, mutect2, varscan2
- SLC14A1 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV58932683; called by muse, mutect2, varscan2
- SLC15A1 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV64730208; called by muse, mutect2, varscan2
- SLC16A7 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs766674596, COSV53892176; called by muse, mutect2, varscan2
- SLC22A14 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs546996289, COSV56197523; called by muse, mutect2, varscan2
- SLC22A25 | c.1631G>A p.S544N | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV60595624, COSV60596640; called by mutect2, varscan2
- SLC25A41 | c.344G>A p.R115K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776448695, COSV51192420; called by muse, varscan2
- SLC26A6 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs970278114, COSV50881296; called by muse, mutect2, varscan2
- SLC2A12 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV51600525; called by muse, mutect2, varscan2
- SLC43A1 | c.1633G>A p.G545R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.043); catalogued as COSV53559370; called by muse, mutect2, varscan2
- SLC6A5 | c.2228G>A p.R743K | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV54227800; called by muse, mutect2, varscan2
- SLC6A6 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62650328; called by muse, mutect2, varscan2
- SLC7A11 | c.1316T>C p.V439A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV54930698; called by muse, varscan2
- SLC8A3 | c.1706T>C p.V569A | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.174); catalogued as COSV63522068; called by muse, mutect2, varscan2
- SLCO6A1 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65809959; called by muse, mutect2, varscan2
- SMARCA4 | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60792276; called by muse, mutect2, varscan2
- SMARCAL1 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV61921148; called by muse, mutect2, varscan2
- SMG8 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as rs193279617, COSV56285724; called by muse, mutect2, varscan2
- SNCAIP | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as rs768676179, COSV54403253; called by mutect2, varscan2
- SORL1 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52755945, COSV99495638; called by muse, mutect2, varscan2
- SPAG17 | c.4287G>A p.T1429= | Splice Region (SNP) | VAF 10/30 reads (33%) | catalogued as rs1336825384, COSV60455899, COSV60460749; called by muse, mutect2, varscan2
- SPATA20 | c.1460A>G p.K487R (on ENST00000356488 / NM_001258372.1; = p.K503R on NM_022827.4) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0.023); catalogued as COSV50067086; called by muse, mutect2, varscan2
- SPEF2 | c.2176G>A p.G726S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61549036; called by muse, mutect2, varscan2
- SPEN | c.3188C>T p.P1063L | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1482914874, COSV65363183; called by muse, mutect2, varscan2
- SPHKAP | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as COSV60882447; called by muse, varscan2
- SPINDOC | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs1445432416, COSV53692819; called by muse, mutect2, varscan2
- SPINT2 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1409082421, COSV56648074; called by muse, mutect2, varscan2
- SPOCD1 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV57096983; called by muse, mutect2, varscan2
- SPTA1 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.182); catalogued as COSV63754630; called by muse, mutect2
- SRBD1 | c.1913G>A p.S638N | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55399804; called by muse, mutect2, varscan2
- STAB2 | c.2921C>T p.S974L | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs758782387, COSV66336179; called by muse, mutect2, varscan2
- STAG1 | c.2544G>A p.M848I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52612362; called by muse, mutect2, varscan2
- STON2 | c.1670G>A p.R557Q (on ENST00000649389 / NM_001366849.2; = p.R500Q on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1430603725, COSV50846135; called by muse, mutect2, varscan2
- SYCP2 | c.584A>C p.E195A | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV62769053; called by muse, mutect2, varscan2
- SZT2 | c.8813C>T p.S2938L (on ENST00000634258 / NM_001365999.1; = p.S2881L on NM_015284.4) | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV65170752; called by muse, mutect2, varscan2
- TACR1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as COSV59482466; called by muse, mutect2, varscan2
- TAF4B | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99300142; called by muse, mutect2, varscan2
- TAS2R16 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV50797293; called by muse, mutect2, varscan2
- TAS2R60 | c.639G>A p.M213I | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as rs141559059, COSV60330146; called by muse, mutect2, varscan2
- TBRG4 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs755900857, COSV51833055; called by muse, mutect2, varscan2
- TBX5 | c.147G>A p.Q49= | Splice Region (SNP) | VAF 60/134 reads (45%) | catalogued as rs1227377137, COSV59862073; called by muse, mutect2, varscan2
- TCF25 | c.1100G>A p.C367Y | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54529029; called by muse, mutect2, varscan2
- TENM2 | c.1414C>T p.H472Y (on ENST00000518659 / NM_001122679.2; = p.H240Y on NM_001080428.3) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs866029407, COSV69132567; called by mutect2, varscan2
- TESMIN | c.1309G>A p.G437R | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.289); catalogued as rs1249551903, COSV54833201; called by muse, mutect2, varscan2
- TEX14 | c.1672G>A p.E558K (on ENST00000240361 / NM_001201457.2; = p.E552K on NM_031272.5) | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as COSV53618904; called by muse, mutect2, varscan2
- TG | c.2645C>T p.S882F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV55079808; called by muse, mutect2, varscan2
- THRAP3 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as rs753960423, COSV63567208; called by muse, mutect2, varscan2
- THSD7A | c.254G>A p.W85* | Nonsense Mutation (SNP) | VAF 42/170 reads (25%) | catalogued as COSV70266202; called by muse, mutect2, varscan2
- THSD7B | c.2479G>A p.G827R | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55697161; called by muse, mutect2, varscan2
- TIMD4 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 261/726 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as rs758058713, COSV50856101; called by muse, mutect2, varscan2
- TIMP3 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56661926; called by muse, mutect2, varscan2
- TJP3 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as rs375489474, COSV53663262; called by muse, mutect2, varscan2
- TLL1 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); catalogued as COSV99287054; called by muse, mutect2, varscan2
- TMC3 | c.3118G>A p.E1040K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.517); catalogued as COSV63923481; called by muse, mutect2, varscan2
- TMCO4 | c.853G>C p.G285R | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53873573; called by muse, mutect2, varscan2
- TMEM132B | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs764860749, COSV54758365, COSV54766311; called by mutect2, varscan2
- TMEM132B | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100168259, COSV54743515; called by muse, mutect2, varscan2
- TMEM132B | c.2434G>A p.D812N | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV54756264; called by muse, mutect2, varscan2
- TMEM132D | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as COSV70608411; called by muse, mutect2, varscan2
- TMEM150B | c.321C>A p.F107L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58593090; called by muse, varscan2
- TMEM155 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1251128996, COSV61795043; called by muse, mutect2, varscan2
- TMPRSS6 | c.1360C>T p.L454F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs1453235639, COSV60976002, COSV60978273; called by muse, mutect2, varscan2
- TNFRSF8 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.112); catalogued as rs1192555839, COSV55797170; called by muse, mutect2, varscan2
- TNN | c.3380G>A p.R1127K | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.09); catalogued as COSV53437472, COSV99512700; called by muse, mutect2, varscan2
- TNS3 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs1368430037, COSV100235442; called by muse, mutect2, varscan2
- TOMM22 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as COSV53265796; called by muse, mutect2, varscan2
- TOX3 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV54866372; called by muse, mutect2, varscan2
- TPO | c.2503G>A p.G835R | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100219603, COSV61103445; called by muse, mutect2, varscan2
- TPTE2 | c.643G>A p.D215N (on ENST00000400230 / NM_199254.2; = p.D138N on NM_130785.3) | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as COSV55022571; called by muse, mutect2
- TPTE2 | c.641G>A p.R214K (on ENST00000400230 / NM_199254.2; = p.R137K on NM_130785.3) | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1185996480, COSV55022590; called by muse, mutect2
- TRAF3IP3 | c.605A>T p.K202I | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV50553741; called by muse, mutect2, varscan2
- TRBV5-1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as rs370038879; called by muse, mutect2, varscan2
- TRDV1 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs375714873; called by muse, mutect2, varscan2
- TRHDE | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as rs147694605, COSV53836154, COSV53868006; called by muse, mutect2, varscan2
- TRIM38 | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as COSV62642350; called by muse, mutect2, varscan2
- TRMT61B | c.835G>C p.V279L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV60258245; called by muse, mutect2, varscan2
- TRPV5 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs781219569, COSV54686784; called by muse, mutect2, varscan2
- TSC2 | c.3658T>A p.S1220T | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); catalogued as COSV54767185; called by muse, varscan2
- TTLL11 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV58647521; called by muse, mutect2, varscan2
- TTN | c.26962C>T p.R8988* (on ENST00000591111; = p.R8061* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as rs1553889325, COSV60118500; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.3455G>A p.G1152E (on ENST00000591111; = p.G1106E on NM_003319.4) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | PolyPhen probably damaging (1); catalogued as COSV60118625; called by muse, varscan2
- TXNL4A | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV54099840; called by muse, mutect2, varscan2
- UBA3 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs750286287, COSV62740696; called by mutect2, varscan2
- UBE2S | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.198); catalogued as rs897520466, COSV52740798; called by muse, mutect2, varscan2
- UBR1 | c.3352G>A p.A1118T | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1271672039, COSV51931123; called by muse, mutect2, varscan2
- UGT2B10 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs554098413, COSV55321157; called by muse, mutect2, varscan2
- UGT8 | c.1343T>C p.I448T | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV60418520; called by muse, mutect2, varscan2
- UNC79 | c.1603C>T p.H535Y (on ENST00000393151 / NM_001346218.2; = p.H358Y on NM_020818.5) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs761679101, COSV56392041; called by muse, mutect2, varscan2
- UQCRC1 | c.888G>A p.W296* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99178967; called by muse, mutect2, varscan2
- UQCRC1 | c.887G>A p.W296* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99178969; called by mutect2, varscan2
- USP17L2 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as COSV61556016; called by muse, mutect2
- USP29 | c.1279A>G p.N427D | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54143561; called by muse, mutect2, varscan2
- VPS13D | c.5260C>T p.Q1754* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV50645542; called by muse, mutect2, varscan2
- VWA7 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 150/326 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63304730; called by muse, mutect2, varscan2
- WDHD1 | c.2071C>G p.P691A | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV62214257, COSV62215112; called by muse, mutect2
- WFIKKN2 | c.1032G>A p.W344* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as rs147499684, COSV60959674; called by muse, mutect2, varscan2
- WIPI2 | c.683G>A p.R228K | Missense Mutation (SNP) | VAF 145/461 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV56589426; called by muse, mutect2, varscan2
- WNK2 | c.5225C>T p.P1742L (on ENST00000297954 / NM_001282394.1; = p.P1705L on NM_006648.3) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.359); catalogued as rs375916312; called by muse, mutect2, varscan2
- WWC1 | c.3095A>C p.Q1032P | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99514853; called by muse, mutect2, varscan2
- WWC1 | c.3096G>C p.Q1032H | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.161); catalogued as COSV99514857; called by muse, mutect2, varscan2
- WWC3 | c.2570C>T p.P857L | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV101081394; called by muse, mutect2, varscan2
- XKR4 | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV59320259; called by muse, mutect2, varscan2
- YLPM1 | c.4748G>A p.W1583* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV53113359; called by muse, mutect2, varscan2
- ZBTB16 | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60094202; called by muse, mutect2, varscan2
- ZFHX3 | c.9631C>A p.P3211T | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV51720586, COSV51721531; called by muse, varscan2
- ZIK1 | c.1223A>G p.K408R | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV56737400; called by muse, varscan2
- ZIM2 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55627278, COSV55628350; called by muse, mutect2, varscan2
- ZNF257 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.115); catalogued as COSV71308659; called by muse, mutect2, varscan2
- ZNF274 | c.1669C>T p.H557Y (on ENST00000610905; = p.H452Y on NM_016324.3) | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58764847, COSV58767273; called by muse, mutect2, varscan2
- ZNF333 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV52886573; called by muse, mutect2, varscan2
- ZNF354A | c.1615C>T p.Q539* | Nonsense Mutation (SNP) | VAF 18/112 reads (16%) | catalogued as COSV100234338, COSV59983641; called by muse, mutect2, varscan2
- ZNF479 | c.1207C>T p.H403Y | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV58638485; called by mutect2, varscan2
- ZNF529 | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV61900782; called by muse, mutect2, varscan2
- ZNF532 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs551203829, COSV60171918; called by muse, mutect2, varscan2
- ZNF641 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56390473; called by muse, mutect2, varscan2
- ZNF665 | c.811C>T p.H271Y (on ENST00000600412; = p.H336Y on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV67215603; called by muse, mutect2, varscan2
- ZNF77 | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58822051; called by muse, varscan2
- ZNF777 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as COSV56098193; called by muse, mutect2, varscan2
- ZNF804A | c.3610C>T p.P1204S | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV56452694; called by muse, varscan2
- ZNF813 | c.140T>G p.L47R | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV67176799; called by muse, mutect2, varscan2
- ZNF816 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV54411449; called by muse, mutect2, varscan2
- ZUP1 | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 23/115 reads (20%) | catalogued as COSV100885080; called by muse, mutect2, varscan2
- ZYG11B | c.2125C>T p.P709S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.038); catalogued as COSV53753768; called by muse, mutect2, varscan2
- ANAPC1 | c.1103G>A p.R368K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.815); called by muse, mutect2
- AREG | c.573G>A p.M191I | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHG1 | c.392A>G p.K131R | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- IGHV3-30 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.397); called by muse, varscan2
- IGHV3OR16-8 | c.154T>C p.Y52H | Missense Mutation (SNP) | VAF 97/312 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- IGLV3-9 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR52E4 | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by mutect2, varscan2
- PRAMEF14 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 121/320 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- RAPGEF6 | c.3153del p.R1052Efs*2 | Frame Shift Del (DEL) | VAF 11/81 reads (14%) | called by mutect2, pindel, varscan2
- SLC24A3 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2
- TRGC1 | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); called by muse, varscan2
- ZNF605 | c.626A>G p.K209R | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ADAM19 | c.2347C>T p.L783= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV57431476; called by muse, mutect2, varscan2
- ADAMTS20 | c.4605G>A p.G1535= | Silent (SNP) | VAF 47/99 reads (47%) | catalogued as COSV67133122; called by muse, mutect2, varscan2
- ADGRG7 | c.537C>T p.I179= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV56297547; called by muse, mutect2, varscan2
- AHNAK | c.13560C>T p.S4520= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV57216383; called by muse, mutect2, varscan2
- AKAP3 | c.1647C>T p.S549= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as COSV57417518; called by muse, mutect2, varscan2
- AMER3 | c.1131C>T p.P377= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs148342332; called by muse, mutect2, varscan2
- AMN1 | c.630G>A p.G210= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV55671789; called by muse, mutect2, varscan2
- ANGPT4 | c.1020G>A p.V340= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as rs777341170, COSV67921832; called by muse, mutect2, varscan2
- ANK3 | c.1428C>T p.S476= | Silent (SNP) | VAF 33/55 reads (60%) | catalogued as rs535590655, COSV55062235; called by muse, mutect2, varscan2
- ANO3 | c.2361C>T p.I787= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV56783271, COSV56786760, COSV56806011; called by muse, mutect2, varscan2
- AOC1 | c.2145C>T p.I715= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs758756420, COSV62869128, COSV62871309; called by muse, mutect2, varscan2
- AOC2 | c.1839G>A p.L613= | Silent (SNP) | VAF 16/138 reads (12%) | catalogued as rs771708967, COSV99520120; called by muse, mutect2, varscan2
- APC2 | c.1515C>T p.L505= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs754414499, COSV52016873; called by muse, mutect2, varscan2
- APOB | c.10932C>T p.F3644= | Silent (SNP) | VAF 99/288 reads (34%) | catalogued as COSV51938861; called by muse, mutect2, varscan2
- APOB | c.4680C>T p.S1560= | Silent (SNP) | VAF 122/406 reads (30%) | catalogued as rs948486350, COSV51938869; ClinVar: likely benign; called by muse, mutect2, varscan2
- APOBR | c.9C>T p.F3= | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as COSV60491349; called by muse, mutect2, varscan2
- APOL3 | c.1152G>A p.E384= (on ENST00000349314 / NM_145640.2; = p.E313= on NM_014349.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 38/111 reads (34%) | catalogued as rs1196722711, COSV62579996; called by muse, mutect2, varscan2
- ARAP1 | c.2562C>T p.A854= (on ENST00000393609 / NM_001040118.2; = p.A609= on NM_015242.4) | Silent (SNP) | VAF 84/199 reads (42%) | catalogued as rs780289845, COSV61991734; called by muse, varscan2
- ARHGAP39 | c.2268C>T p.D756= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV52771352; called by muse, mutect2, varscan2
- ARHGEF17 | c.3945C>T p.I1315= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs531570951, COSV55233378; called by muse, mutect2, varscan2
- ASH1L | c.3054C>T p.L1018= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV64204944; called by muse, mutect2, varscan2
- ASIC3 | c.381C>T p.R127= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs560534800, COSV52505650; called by muse, varscan2
- ASXL2 | c.1233C>T p.S411= | Silent (SNP) | VAF 78/260 reads (30%) | catalogued as COSV55460125; called by muse, mutect2, varscan2
- ATP13A5 | c.717C>T p.V239= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV60870420; called by muse, mutect2, varscan2
- ATP8A1 | c.3432C>T p.I1144= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs748299606, COSV52531451; called by mutect2, varscan2
- ATP8A1 | c.2058G>A p.G686= | Silent (SNP) | VAF 52/145 reads (36%) | catalogued as rs1269803445, COSV52537110; called by muse, mutect2, varscan2
- B3GNT9 | c.891C>T p.A297= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs1320358023, COSV54627649; called by muse, mutect2, varscan2
- BATF3 | c.123G>A p.R41= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs770860309, COSV99695961; called by muse, mutect2, varscan2
- BHLHE22 | c.1074C>T p.S358= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV58861989; called by muse, mutect2, varscan2
- BIRC6 | c.13920C>T p.P4640= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs201179936, COSV101428223; called by muse, mutect2, varscan2
- BLK | c.117G>C p.P39= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs745995566, COSV52050250, COSV52052888; called by muse, mutect2, varscan2
- BPIFB6 | c.552G>A p.V184= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as COSV62755480, COSV62755973; called by muse, mutect2, varscan2
- BTBD16 | c.1368C>T p.A456= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs778015817, COSV99584739; called by muse, mutect2, varscan2
- BTBD16 | c.1369C>T p.L457= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV99584742; called by muse, mutect2, varscan2
- C16orf46 | c.1047C>T p.I349= | Silent (SNP) | VAF 40/153 reads (26%) | catalogued as rs1386134446, COSV55151578; called by muse, mutect2, varscan2
- C1S | c.75C>T p.S25= | Silent (SNP) | VAF 62/112 reads (55%) | catalogued as COSV61071118; called by muse, mutect2, varscan2
- C9orf152 | c.588C>T p.F196= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV68762880; called by muse, mutect2, varscan2
- CACNA1E | c.4230C>T p.F1410= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV62396516; called by muse, varscan2
- CACNA2D3 | c.1761G>A p.V587= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs769443944, COSV55553960; called by muse, varscan2
- CACNG7 | c.693C>T p.F231= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as rs1349628450, COSV55814923; called by muse, mutect2, varscan2
- CCDC158 | c.1821G>A p.K607= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as COSV101187234, COSV66356258; called by muse, varscan2
- CCDC158 | c.1557C>T p.I519= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV66356261; called by muse, varscan2
- CCDC91 | c.351C>T p.A117= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV60343419; called by muse, mutect2
- CCL23 | c.408G>A p.K136= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- CCNF | c.316C>T p.L106= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV53540610; called by muse, mutect2, varscan2
- CEACAM18 | c.72G>A p.G24= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV67283172; called by muse, mutect2
- CEMIP | c.336C>T p.A112= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV54992929, COSV54999225; called by muse, mutect2, varscan2
- CFAP299 | c.144A>G p.L48= | Silent (SNP) | VAF 42/146 reads (29%) | catalogued as rs1305273198, COSV63879766; called by muse, mutect2, varscan2
- CFAP65 | c.225C>T p.V75= (on ENST00000341552 / NM_194302.4; = p.V10= on NM_152389.4) | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs767323675, COSV55390621; called by muse, varscan2
- CHD3 | c.3429C>T p.I1143= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV57876258; called by muse, varscan2
- CHODL | c.207C>T p.L69= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1254406412, COSV54733066; called by muse, mutect2, varscan2
- CHRND | c.831G>A p.K277= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV51320927, COSV99285889; called by muse, mutect2, varscan2
- CIPC | c.996C>T p.I332= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV62377072; called by muse, mutect2, varscan2
- CLCN1 | c.1102C>T p.L368= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as COSV58370677, COSV58372294, COSV58375171; called by muse, mutect2, varscan2
- CLEC5A | c.189C>T p.T63= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV69397355; called by muse, mutect2, varscan2
- CLSTN2 | c.1287G>A p.K429= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV71720049; called by muse, mutect2, varscan2
- CNTN4 | c.492C>T p.S164= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100639197, COSV61867239; called by muse, mutect2, varscan2
- CNTNAP2 | c.912G>A p.E304= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs372998403; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL1A1 | c.1695C>T p.P565= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs761635519, COSV56802808; called by muse, mutect2, varscan2
- COL3A1 | c.3114C>T p.G1038= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs982248094, COSV58590044; called by muse, mutect2, varscan2
- COL6A3 | c.5580C>T p.S1860= | Silent (SNP) | VAF 61/166 reads (37%) | catalogued as COSV55093084; called by muse, mutect2, varscan2
- CRHR1 | c.390C>T p.S130= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV53279828; called by muse, mutect2, varscan2
- CROT | c.1404C>T p.S468= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs765824864, COSV100519497; called by muse, mutect2, varscan2
- CSMD1 | c.7536C>T p.F2512= (on ENST00000520002; = p.F2511= on NM_033225.6) | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs777543070, COSV59291970; called by mutect2, varscan2
- CYP2C19 | c.531G>A p.V177= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV64908063; called by muse, mutect2, varscan2
- DBT | c.45G>A p.G15= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV64495642; called by muse, varscan2
- DCAF12L1 | c.363C>T p.F121= | Silent (SNP) | VAF 21/28 reads (75%) | catalogued as rs775537701, COSV64421979; called by muse, mutect2, varscan2
- DEFB4A | c.18C>T p.L6= | Silent (SNP) | VAF 26/158 reads (16%) | catalogued as rs760348096, COSV56362456; called by muse, mutect2, varscan2
- DISP1 | c.1227C>T p.L409= | Silent (SNP) | VAF 173/476 reads (36%) | catalogued as COSV52660326; called by muse, mutect2, varscan2
- DNAH3 | c.8967G>A p.G2989= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as COSV54527428; called by muse, mutect2, varscan2
- DNAH5 | c.6396G>A p.R2132= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV54231281; called by muse, mutect2, varscan2
- DNAH8 | c.5256C>T p.F1752= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs772470999, COSV59438427; called by muse, mutect2, varscan2
- DOCK9 | c.834C>T p.I278= (on ENST00000376460 / NM_001366676.2; = p.I279= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV59632466; called by muse, mutect2, varscan2
- DOLPP1 | c.30C>T p.P10= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as rs771201297, COSV59910511, COSV59910575; called by muse, mutect2, varscan2
- DPYSL5 | c.324C>T p.S108= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV56513074; called by muse, mutect2, varscan2
- DSE | c.1242C>T p.F414= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV59063190; called by muse, mutect2, varscan2
- EBF2 | c.1650C>T p.G550= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs755991317, COSV68778421; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1656G>A p.T552= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs781718047, COSV62568311; called by muse, mutect2, varscan2
- EEF2K | c.1582C>T p.L528= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs544902060, COSV53782843; called by muse, varscan2
- EFCAB6 | c.3123G>A p.K1041= | Silent (SNP) | VAF 62/354 reads (18%) | catalogued as COSV53065097; called by muse, varscan2
- EFEMP2 | c.891C>T p.A297= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV57260424; called by muse, mutect2, varscan2
- EFL1 | c.2670C>T p.V890= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV51606454; called by muse, mutect2, varscan2
- ELP2 | c.1866C>T p.F622= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV60851577; called by muse, mutect2, varscan2
- EML5 | c.2628G>A p.E876= | Silent (SNP) | VAF 88/245 reads (36%) | catalogued as rs764389071, COSV61345268, COSV61346837; called by muse, mutect2, varscan2
- ENAM | c.780G>A p.G260= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV68536134; called by muse, mutect2, varscan2
- EPHA2 | c.579C>T p.S193= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs745413370, COSV64453405; called by muse, mutect2, varscan2
- EPHA4 | c.537G>A p.K179= | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as COSV56032164, COSV56035431; called by muse, mutect2, varscan2
- EPHA6 | c.2400C>T p.A800= (on ENST00000389672 / NM_001080448.3; = p.A192= on NM_173655.4) | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV67576021; called by muse, mutect2, varscan2
- EVA1A | c.75C>T p.S25= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV52059295; called by muse, mutect2, varscan2
- F11 | c.1164C>T p.I388= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as rs1165954112, COSV53001317; called by muse, mutect2, varscan2
- FAM110C | c.723G>A p.S241= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs756635874, COSV59656074; called by muse, mutect2, varscan2
- FAM177B | c.327G>A p.R109= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV62601076, COSV62601368; called by muse, mutect2
- FAM83B | c.459G>A p.V153= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV60922927; called by mutect2, varscan2
- FAM83B | c.1497C>T p.S499= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs561363029, COSV60922935; called by muse, mutect2, varscan2
- FAT3 | c.882G>A p.A294= | Silent (SNP) | VAF 38/247 reads (15%) | catalogued as rs200428460, COSV53121432; called by muse, mutect2, varscan2
- FAT4 | c.5412G>A p.R1804= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV58689805; called by muse, varscan2
- FAT4 | c.9144C>T p.S3048= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV58689833; called by muse, varscan2
- FAT4 | c.13890C>T p.I4630= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs267600016, COSV58676374; called by muse, mutect2, varscan2
- FBN2 | c.1152G>A p.T384= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs267600336, COSV52519333; ClinVar: likely benign; called by mutect2, varscan2
- FBXL19 | c.1960C>T p.L654= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs1474650508, COSV57942998; called by muse, mutect2, varscan2
- FCER1A | c.102G>A p.L34= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs763332773, COSV100929300, COSV63667455; called by muse, mutect2, varscan2
- FCGBP | c.12495G>A p.G4165= | Silent (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- FCGBP | c.5337G>A p.S1779= | Silent (SNP) | VAF 61/112 reads (54%) | catalogued as rs1411385381; called by muse, mutect2, varscan2
- FCGR3B | c.225C>T p.F75= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV54210293; called by mutect2, varscan2
- FCN1 | c.108G>A p.V36= | Silent (SNP) | VAF 51/156 reads (33%) | catalogued as COSV100878879, COSV65662517; called by muse, varscan2
- FCRL5 | c.1788C>T p.I596= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV62515522; called by muse, mutect2, varscan2
- FERMT3 | c.285C>T p.P95= | Silent (SNP) | VAF 58/183 reads (32%) | catalogued as rs1231698215, COSV99656538; called by muse, mutect2, varscan2
- FGG | c.459G>A p.K153= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs750418989, COSV60195633; called by muse, mutect2, varscan2
- FILIP1 | c.228C>T p.S76= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV52732404; called by muse, mutect2, varscan2
- FMO2 | c.1116C>T p.I372= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV52948269; called by muse, mutect2, varscan2
- FOXK1 | c.798C>T p.Y266= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV61066529; called by muse, mutect2, varscan2
- GAST | c.219C>T p.S73= | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as COSV61475618; called by muse, mutect2, varscan2
- GIMAP8 | c.1389C>T p.V463= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as rs1357448636, COSV56231978; called by muse, mutect2, varscan2
- GINM1 | c.486C>T p.L162= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV66389918; called by muse, mutect2, varscan2
- GJB5 | c.207C>T p.F69= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV58356387; called by muse, mutect2, varscan2
- GLYATL2 | c.63C>T p.I21= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs1268731659, COSV54850245; called by muse, mutect2, varscan2
- GOLGA6B | c.618G>A p.K206= | Silent (SNP) | VAF 13/194 reads (7%) | catalogued as COSV69770199; called by muse, mutect2
- GPR32 | c.663C>T p.F221= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs777672930, COSV54514752; called by muse, mutect2, varscan2
- GRB7 | c.657C>T p.L219= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV58448515; called by muse, mutect2, varscan2
- GRM3 | c.2070C>T p.F690= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs267601606, COSV64473186; called by mutect2, varscan2
- GRM7 | c.1131G>A p.T377= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs139183375; called by muse, mutect2, varscan2
- GRM7 | c.1815C>T p.T605= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs1474247725, COSV63147228; called by muse, mutect2, varscan2
- HAO2 | c.426C>T p.I142= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV58040010; called by muse, varscan2
- HARBI1 | c.57C>T p.H19= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as COSV56319144, COSV56319938; called by muse, mutect2, varscan2
- HCK | c.783C>T p.S261= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV52943505; called by muse, mutect2, varscan2
- HEATR5A | c.2076C>T p.N692= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV66341811; called by muse, mutect2, varscan2
- HECW2 | c.3981C>T p.F1327= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV53662262; called by muse, varscan2
- HEXIM1 | c.231G>A p.Q77= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV60177162; called by muse, varscan2
- HIF1A | c.984G>A p.K328= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV60188348, COSV60189589, COSV60191620; called by muse, varscan2
- HIVEP3 | c.1845C>T p.S615= | Silent (SNP) | VAF 65/140 reads (46%) | catalogued as COSV56016741; called by muse, mutect2, varscan2
- HMBOX1 | c.1215C>T p.A405= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV55068982; called by muse, mutect2, varscan2
- HMCN1 | c.6933C>T p.S2311= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs752504748, COSV54907402; called by mutect2, varscan2
- HNF4A | c.444C>T p.S148= | Silent (SNP) | VAF 31/195 reads (16%) | catalogued as COSV57384227; called by muse, mutect2, varscan2
- HOXB1 | c.492G>A p.K164= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV53317562; called by muse, varscan2
- HOXC11 | c.474C>T p.A158= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV54533388; called by muse, mutect2
- HS3ST3A1 | c.633C>T p.I211= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV52375823; called by muse, mutect2, varscan2
- HTR1D | c.964C>T p.L322= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV58448334; called by muse, mutect2, varscan2
- HTR1D | c.378C>T p.I126= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV58448340; called by muse, mutect2, varscan2
- HYDIN | c.7425C>T p.D2475= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV59259604; called by muse, mutect2, varscan2
- IDH1 | c.1158G>A p.V386= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV61626877; called by mutect2, varscan2
- IDO2 | c.705G>A p.R235= (on ENST00000389060; = p.R248= on NM_194294.2) | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV58424667; called by muse, mutect2, varscan2
- IGHMBP2 | c.1722C>A p.A574= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV54823101, COSV54826915; called by muse, mutect2, varscan2
- IQCF3 | c.330C>T p.R110= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV71309532; called by muse, mutect2, varscan2
223 further variants in this file (0 protein-altering or splice-affecting, 206 silent, 17 other) are not listed here.
